Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A656, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A656-01A (Primary Tumor).

ICD 0-3
Carcinoma, papillary 8260/3
Site of Kidney NOS C64.9
JW 5/16/13

Collection Date:

FINAL DIAGNOSIS:

RENAL MASS, LEFT, PARTIAL NEPHRECTOMY -

- RENAL CELL CARCINOMA, WITH FEATURES OF BOTH PAPILLARY (PAPILLARY TYPE 2) AND CLEAR CELL (CONVENTIONAL) TYPES (see comment). *per TSS, clear cell features = 5%*
- CARCINOMA MEASURES 1.7 cm IN GREATEST DIMENSION.
- CARCINOMA IS CONFINED TO THE KIDNEY.
- FUHRMAN NUCLEAR GRADE IS 3 OF 4.
- ALL SURGICAL MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA.
- NO LYMPHOVASCULAR INVASION IS SEEN.
- LIMITED BACKGROUND RENAL PARENCHYMA WITH MODERATE MIXED AND FOCALLY XANTHOGRANULOMATOUS INFLAMMATION, INCLUDING HEMOSIDERIN-LADEN MACROPHAGES.
- PATHOLOGIC TNM STAGE (AJCC 7th EDITION): pT1a NX MX.

COMMENT:

Histologic sections show a malignant neoplasm composed of architecturally-crowded papillae of eosinophilic cells with abundant stromal macrophages. Moreover, foci of cytologically malignant cells with distinct clear cell features are also identified in the periphery of this lesion. Results of paraffin section immunohistochemical analysis also highlight both cell populations (see microscopic description), thereby supporting the above rendered diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:

Partial nephrectomy

LATERALITY:

Left

TUMOR SITE:

Not specified

FOCALITY:

Unifocal

TUMOR SIZE:

Greatest dimension: 1.7 cm

Additional dimensions: 1.5 x 1.5 cm

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G3

PATHOLOGIC STAGING (pTNM):

pT1a

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS:

Margins uninvolved by invasive carcinoma

ADRENAL GLAND:

Not present

LYMPH-VASCULAR INVASION (LVI):

Absent/not identified

KIDNEY-RESIDUAL TUMOR (R):

R0

Source: NCI Genomic Data Commons file 02968a64-a0b5-410e-b56d-f065c60e68fe (TCGA-B1-A656.F08B2D8F-D5D3-4DCC-9E7B-EE6D655712BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).